Somatic mutation profile of tumor specimen TCGA-2Z-A9JR-01A (aliquot TCGA-2Z-A9JR-01A-12D-A42J-10) from TCGA case TCGA-2Z-A9JR, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 57.3 years (20,932 days).
Specimen TCGA-2Z-A9JR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c670eda9-0e75-4b54-a12e-6fdcf48c123f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Z-A9JR-10A (Blood Derived Normal), aliquot TCGA-2Z-A9JR-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c155dcc4-989d-444f-a5f4-b22adc7a2205

The open-access MAF lists 56 somatic variants for this specimen: 42 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 13, Frame Shift Del 8, Nonsense Mutation 3, In Frame Del 2, Splice Site 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKS1A | c.885C>A p.S295R | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100831938; called by muse, mutect2, varscan2
- APC | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57353104, COSV99964254; called by muse, mutect2, varscan2
- CDC25C | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.021); catalogued as COSV100086462; called by muse, mutect2, varscan2
- CDC42BPA | c.4055A>G p.K1352R (on ENST00000334218 / NM_001366019.2; = p.K1339R on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.107); catalogued as COSV100503330; called by muse, mutect2
- CENPF | c.7048A>G p.T2350A | Missense Mutation (SNP) | VAF 74/216 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1355387450, COSV100871388; called by muse, mutect2, varscan2
- CTSA | c.275A>T p.D92V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV99509576; called by muse, mutect2, varscan2
- DNAJB12 | c.1154T>A p.M385K (on ENST00000338820; = p.M351K on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV100123595; called by muse, mutect2, varscan2
- FBXL17 | c.1266T>A p.C422* | Nonsense Mutation (SNP) | VAF 65/256 reads (25%) | catalogued as COSV100670177; called by muse, mutect2, varscan2
- FGF5 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 19/262 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as rs745662451, COSV56892905; called by muse, mutect2
- GABPB1 | c.514G>C p.D172H | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.994); catalogued as COSV99589478; called by muse, mutect2, varscan2
- GSTCD | c.1496A>G p.N499S (on ENST00000360505 / NM_001031720.3; = p.N412S on NM_024751.3) | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100853742; called by muse, mutect2, varscan2
- GTF2H2C | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 130/484 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV101053381; called by muse, mutect2, varscan2
- GTF2H2C | c.95C>G p.A32G | Missense Mutation (SNP) | VAF 130/482 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV101053382; called by muse, mutect2, varscan2
- IGF2R | c.1448G>C p.R483P | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV100806644; called by muse, mutect2, varscan2
- KCNH2 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.186); catalogued as rs1157236353, CD1314039, COSV100058698; called by muse, mutect2, varscan2
- KCNH6 | c.548A>G p.Q183R | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); catalogued as COSV100120686; called by muse, mutect2, varscan2
- KCNQ2 | c.1720G>A p.G574S (on ENST00000359125 / NM_172107.4; = p.G546S on NM_004518.6) | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60549717; called by muse, mutect2, varscan2
- KRT25 | c.884C>A p.A295D | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV100379744; called by muse, mutect2, varscan2
- MATN2 | c.1228A>T p.K410* | Nonsense Mutation (SNP) | VAF 22/99 reads (22%) | catalogued as COSV99645443; called by muse, mutect2, varscan2
- PCLAF | c.289A>T p.K97* | Nonsense Mutation (SNP) | VAF 27/108 reads (25%) | catalogued as COSV100256763; called by muse, mutect2, varscan2
- PDE8B | c.1241G>A p.R414K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as COSV53748255; called by muse, mutect2, varscan2
- PEX13 | c.441G>T p.M147I | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); catalogued as COSV99692566; called by muse, mutect2, varscan2
- PGD | c.688T>C p.S230P | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99581035; called by muse, mutect2, varscan2
- PHLDB1 | c.3935A>T p.Y1312F | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV99874085; called by muse, mutect2, varscan2
- RPIA | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52169777; called by muse, mutect2, varscan2
- RPRD2 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.953); catalogued as rs781934080, COSV100954678; called by muse, mutect2, varscan2
- SAP30BP | c.623T>G p.M208R | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99502614; called by muse, mutect2, varscan2
- TG | c.1074T>C p.C358= | Splice Region (SNP) | VAF 27/79 reads (34%) | catalogued as COSV99598275; called by muse, mutect2, varscan2
- VPS13A | c.1953G>T p.L651F | Missense Mutation (SNP) | VAF 81/237 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100651868; called by muse, mutect2, varscan2
- ZNF35 | c.1217T>A p.I406N | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as COSV99939941; called by muse, mutect2, varscan2
- ZNF91 | c.433T>C p.C145R | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.861); catalogued as rs1485530942, COSV100321833; called by muse, mutect2, varscan2
- AC098582.1 | c.1267del p.I423Sfs*38 | Frame Shift Del (DEL) | VAF 40/150 reads (27%) | called by mutect2, pindel, varscan2
- ANKRD30A | c.2495_2497del p.I832del (on ENST00000611781; = p.I776del on NM_052997.2) | In Frame Del (DEL) | VAF 29/213 reads (14%) | called by mutect2, pindel, varscan2
- APC2 | c.2352del p.S785Hfs*252 | Frame Shift Del (DEL) | VAF 26/102 reads (25%) | called by mutect2, pindel, varscan2
- ARMH3 | c.1529del p.N510Mfs*14 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- ATP5PD | c.152del p.A51Vfs*27 | Frame Shift Del (DEL) | VAF 44/107 reads (41%) | called by mutect2, pindel, varscan2
- CCDC146 | c.468_473del p.I157_I158del | In Frame Del (DEL) | VAF 23/75 reads (31%) | called by mutect2, pindel, varscan2
- KMT2E | c.2087_2100del p.T696Rfs*5 | Frame Shift Del (DEL) | VAF 117/390 reads (30%) | called by mutect2, pindel, varscan2
- MSH4 | c.974_977del p.N325Ifs*14 | Frame Shift Del (DEL) | VAF 100/297 reads (34%) | called by mutect2, varscan2
- STIM1 | c.837_850del p.V280Efs*5 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- TXNIP | c.251-23_252del p.X84_splice | Splice Site (DEL) | VAF 10/77 reads (13%) | called by mutect2, pindel
- VCPIP1 | c.1472del p.L491Cfs*12 | Frame Shift Del (DEL) | VAF 32/92 reads (35%) | called by mutect2, pindel, varscan2
- ABCA3 | c.4440C>T p.Y1480= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs367951064, COSV57052128; called by muse, mutect2, varscan2
- ASRGL1 | c.558A>T p.T186= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV100077586; called by muse, mutect2, varscan2
- CDKN2C | c.360G>A p.E120= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV99395645; called by muse, mutect2, varscan2
- DAB2IP | c.3426T>C p.D1142= (on ENST00000408936; = p.D1114= on NM_032552.3) | Silent (SNP) | VAF 45/99 reads (45%) | catalogued as COSV99404420; called by muse, mutect2, varscan2
- H1-7 | c.492G>A p.A164= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV100622151; called by muse, mutect2
- NAV1 | c.3672G>T p.A1224= | Silent (SNP) | VAF 47/148 reads (32%) | catalogued as rs771921539, COSV99817996; called by muse, mutect2, varscan2
- NFAT5 | c.1794A>T p.P598= | Silent (SNP) | VAF 117/218 reads (54%) | catalogued as COSV100590293; called by muse, mutect2, varscan2
- OTUD4 | c.1755T>A p.P585= (on ENST00000447906 / NM_001366057.1; = p.P520= on NM_001102653.1) | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as COSV101485853; called by muse, mutect2, varscan2
- PCDHGB5 | c.210G>A p.S70= | Silent (SNP) | VAF 84/255 reads (33%) | catalogued as rs1206051880, COSV99547987; called by muse, mutect2, varscan2
- POTEF | c.2760C>T p.A920= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs1456565875, COSV100664439; called by muse, varscan2
- RAG2 | c.231T>A p.T77= | Silent (SNP) | VAF 36/125 reads (29%) | catalogued as COSV100270959, COSV57559687; called by muse, mutect2, varscan2
- SRCAP | c.3204C>T p.G1068= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99348875; called by muse, mutect2, varscan2
- UBR4 | c.4488C>T p.T1496= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV100919874, COSV64394554; called by muse, mutect2, varscan2
- CPLANE1 | c.*3842C>T | 3'UTR (SNP) | VAF 59/161 reads (37%) | catalogued as COSV99949166; called by muse, mutect2, varscan2
